Surgical pathology report (de-identified scan), TCGA case TCGA-PC-A5DK, project TCGA-SARC (Sarcoma), tissue source site Fox Chase, specimen TCGA-PC-A5DK-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN
SURGICAL PATHOLOGY REPORT

DOB:
Sex: M
Location:
Date Collected
Date Received
Physician:
Copy To:
Clinical History/Diagnosis: Right Adrenal Mass

ICD-O-3
Neuromyosarcoma NOS 8890/3
Site: Retroperitoneum 8480
JW 5/24/13

Source of Specimen(s):
Right adrenal mass

Gross Description:
Received in one part.

Source of Tissue: 1. Labeled #1, "right adrenal mass"

Frozen Section Diagnosis: 1FS- BENIGN OR LOW GRADE SPINDLE CELL
NEOPLASM,
POSSIBLY SMOOTH MUSCLE IN ORIGIN, DIFFERENTIAL DIAGNOSIS
INCLUDES NEURONAL
OR GIST. FINAL DEFERRED TO PERMANENT PER

Gross Description: Received fresh is a bosselated gray-tan rubbery firm mass measuring 10 x 9 x 9 cm and has some attached associated fat measuring up to 5 cm. Sections through the fat discloses an adrenal gland measuring 3 x 1.5 x 1.3 cm and is grossly normal appearing. Sections through the mass discloses bulging white whorling surface. No hemorrhage, cystic areas or calcifications are found. Grossly the mass appears separate and does not involve the adrenal gland. One representative section was selected for frozen section and submitted in 1FS. Additional sections submitted in 1A-1J with tumor in relationship to adrenal gland in 1A-1D.

Designation of Sections: Representative sections 1A-1J

Summary of Sections:

Final Diagnosis:
Right adrenal mass, resection:

[page 2 of 2]
- Consistent with low grade leiomyosarcoma (10 cm), see note.
- Adjacent adrenal gland not involved by tumor.

Note: The tumor shows increased cellularity, nuclear atypia and a low mitotic rate (approximately 1-2/10HPF) with a rare atypical mitosis. Necrosis is not seen. Immunohistochemistry stains show that the tumor cells are positive for desmin and muscle specific actin (HHF35), negative for CD34, C-kit, S100 and HMB45. Case reviewed with _____ who concurs in the diagnosis.

These tests were developed and their performance characteristics determined by the immunohistochemistry laboratory at the

These tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1998 (CLIA) as qualified to perform high complexity clinical testing.

Source: NCI Genomic Data Commons file be288731-f9c7-4e5b-9610-71b62fd10a61 (TCGA-PC-A5DK.64FC9D8C-5171-4034-891E-D6F2547032B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).